Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4987, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4987-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA-BP-4987

Clinical Diagnosis & History:

s/p syncopal episode; u/s positive for renal mass.

Specimens Submitted:

1: KIDNEY, LEFT; PARTIAL NEPHRECTOMY

DIAGNOSIS:

1. KIDNEY, LEFT; PARTIAL NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 4.3 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Minimal arteriosclerotic changes

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1.)The specimen is received fresh for frozen section and is labeled "left kidney tumor, stitch marks deep margin". It consists of a 4.3 x 4.0 x 3.5 cm portion of kidney, surrounded on its capsular surface by yellow fat measuring 1.5 cm in thickness, with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal an ovoid circumscribed heterogeneous mass, with fibrous bands, myxoid areas, hemorrhagic areas and golden yellow areas measuring 4.3 x 3.5 x 3.5 cm. The clearance from the resection margin is 0.1 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. A gross photograph has been taken. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control
T - tumor
M - margin

Summary of Sections:

Part 1: KIDNEY, LEFT; PARTIAL NEPHRECTOMY

Block	Sect. Site	PCs
1	FSC	1
3	M	3
3	T	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM, SUGGESTIVE OF CLEAR CELL CARCINOMA ON REPRESENTATIVE SECTION. MARGIN AT STITCH NEGATIVE FOR TUMOR
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 48c07e10-5872-44c6-b6be-84c342d0cc98 (TCGA-BP-4987.52C79F63-A2F5-4716-B76D-393E5B480D6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).